Somatic mutation profile of tumor specimen 0DEK1N from CCDI case PBBPTC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myofibroma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.7 years (261 days).
Specimen 0DEK1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb3f4c9-5b65-4785-b185-39a7d2be983c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEJZ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a7f4692-d756-4e39-8acd-22a443ddd6a2

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHROOM4 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 126/144 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782490910; called by muse, mutect2, varscan2
- ACAT2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SNUPN | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- TTBK1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- MSI2 | c.727+4577G>A | Intron (SNP) | VAF 48/326 reads (15%) | called by muse, mutect2, varscan2
- NAPSA | c.*20C>A | 3'UTR (SNP) | VAF 94/210 reads (45%) | called by muse, mutect2, varscan2
- SH3BP5L | c.376-166T>C | Intron (SNP) | VAF 13/187 reads (7%) | called by muse, mutect2
